Somatic mutation profile of tumor specimen 0DG87R from CCDI case PBBSUU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 10.9 years (3,963 days).
Specimen 0DG87R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebfb8c34-cc9b-4c34-a93d-94be9915e36f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aadab61-d701-4145-8680-76034049a958

The open-access MAF lists 94 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Intron 11, 3'UTR 4, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 162/1026 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- ADAMTS7 | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as rs764662798; called by muse, mutect2
- APCS | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 82/846 reads (10%) | catalogued as COSV54817981; called by muse, mutect2
- BEGAIN | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs776626054; called by muse, mutect2, varscan2
- C10orf71 | c.3814G>A p.A1272T | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs1472853354, COSV60505092; called by muse, mutect2
- ELL2 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 114/667 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as rs1376691630; called by muse, mutect2, varscan2
- FBXO30 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 94/1192 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs532426956, COSV99394954; called by muse, mutect2
- HCFC1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 116/519 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60071564; called by muse, mutect2, varscan2
- HLX | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 26/896 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65045583; called by muse, mutect2
- IFNL2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 24/698 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as rs1303936782; called by muse, mutect2
- KIF2A | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 98/1146 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs1052613653, COSV66946111; called by muse, mutect2
- KMT5B | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 32/877 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1250854401; called by muse, mutect2
- LIPH | c.1142G>T p.R381I | Missense Mutation (SNP) | VAF 54/664 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV99955785; called by muse, mutect2
- LPA | c.3148G>T p.G1050W | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV60305153; called by muse, mutect2
- MAD1L1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 114/547 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777976890, COSV99764943; called by muse, mutect2, varscan2
- MGAM | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 93/452 reads (21%) | catalogued as COSV71885128; called by muse, mutect2, varscan2
- OBSCN | c.13738G>A p.E4580K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs981166065, COSV52762918; called by muse, mutect2, varscan2
- PALB2 | c.2797T>G p.C933G | Missense Mutation (SNP) | VAF 36/763 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295650692; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB15 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 4/131 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV50862481; called by muse, mutect2
- PPEF1 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 70/1108 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs767043387, COSV100583860; called by muse, mutect2
- PRG4 | c.2933C>T p.T978I | Missense Mutation (SNP) | VAF 102/1060 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100798177; called by muse, mutect2
- SNTG1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 315/1418 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs764804995, COSV52440797; called by muse, mutect2, varscan2
- TERT | c.2852G>C p.R951P | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.693); catalogued as COSV57204908; called by muse, mutect2, varscan2
- ZFHX4 | c.7697C>T p.S2566F | Missense Mutation (SNP) | VAF 60/1173 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs765662207, COSV51503245; called by muse, mutect2
- ZNF354B | c.281C>A p.T94K | Missense Mutation (SNP) | VAF 65/1340 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1440218599; called by muse, mutect2
- ADGRF4 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH1A2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AP2A2 | c.2677dup p.I893Nfs*32 | Frame Shift Ins (INS) | VAF 39/305 reads (13%) | called by mutect2, varscan2
- COL24A1 | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 83/1004 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.315); called by muse, mutect2
- CREBZF | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYLC1 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 107/1509 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- DNAH12 | c.2350G>A p.E784K (on ENST00000351747; = p.E807K on NM_001366028.2) | Missense Mutation (SNP) | VAF 66/780 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2
- ENHO | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by mutect2, varscan2
- FRYL | c.2969T>C p.L990P | Missense Mutation (SNP) | VAF 102/818 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FSCN3 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- KIAA1210 | c.4561A>G p.T1521A | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- KRTAP24-1 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 50/663 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2
- LIPM | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 34/564 reads (6%) | called by muse, mutect2
- MOSPD2 | c.1262C>A p.A421E | Missense Mutation (SNP) | VAF 47/1631 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2
- MTMR1 | c.873G>T p.L291F | Missense Mutation (SNP) | VAF 168/510 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MTSS2 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC7 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 119/580 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MYOD1 | c.491T>G p.L164R | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASA3 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- RNF135 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 36/597 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2
- ROBO3 | c.906-1G>A p.X302_splice | Splice Site (SNP) | VAF 68/517 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN10 | c.973T>G p.C325G | Missense Mutation (SNP) | VAF 125/1458 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.102); called by muse, mutect2
- SPANXN3 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 221/742 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SVOPL | c.1232A>C p.N411T (on ENST00000419765; = p.N259T on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/819 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2
- TEC | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 80/664 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.173); called by muse, varscan2
- TNKS2 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 91/1338 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2
- TRIB3 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ZNF132 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 54/838 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- ZNF385D | c.975dup p.E326Rfs*75 | Frame Shift Ins (INS) | VAF 50/468 reads (11%) | called by mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 44/1198 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZNF680 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 107/759 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACHE | c.1743G>A p.E581= | Silent (SNP) | VAF 107/506 reads (21%) | called by muse, mutect2, varscan2
- ANKRD44 | c.2712G>A p.K904= | Silent (SNP) | VAF 50/1253 reads (4%) | called by muse, mutect2
- ARID5B | c.2244G>T p.R748= | Silent (SNP) | VAF 102/525 reads (19%) | catalogued as rs1177645299; called by muse, mutect2, varscan2
- ATP8B2 | c.765C>T p.F255= (on ENST00000672630; = p.F222= on NM_001005855.2) | Silent (SNP) | VAF 42/1070 reads (4%) | called by muse, mutect2
- CCDC178 | c.2595C>T p.N865= (on ENST00000383096 / NM_001105528.3; = p.N827= on NM_198995.3) | Silent (SNP) | VAF 93/709 reads (13%) | catalogued as rs959855208, COSV55790414; called by muse, mutect2, varscan2
- CCDC80 | c.2496C>T p.F832= | Silent (SNP) | VAF 232/921 reads (25%) | catalogued as rs779103715; called by muse, mutect2, varscan2
- CSAG1 | c.54G>A p.R18= | Silent (SNP) | VAF 136/828 reads (16%) | called by muse, mutect2, varscan2
- CYP7A1 | c.1317G>A p.S439= | Silent (SNP) | VAF 108/1534 reads (7%) | catalogued as rs754486556, COSV56963233; called by muse, mutect2
- FAM135B | c.1881G>A p.K627= | Silent (SNP) | VAF 82/373 reads (22%) | catalogued as rs776479163, COSV52760931; called by muse, mutect2, varscan2
- FAM135B | c.33G>A p.S11= | Silent (SNP) | VAF 166/1804 reads (9%) | catalogued as rs376994267, COSV99355951; called by muse, mutect2
- IDE | c.820T>C p.L274= | Silent (SNP) | VAF 40/1218 reads (3%) | called by muse, mutect2
- LGR6 | c.2049G>T p.L683= (on ENST00000367278 / NM_001017403.1; = p.L631= on NM_021636.3) | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- MATN2 | c.2028G>A p.Q676= | Silent (SNP) | VAF 70/1151 reads (6%) | catalogued as rs777785582; called by muse, mutect2
- MIOX | c.309G>A p.A103= | Silent (SNP) | VAF 46/525 reads (9%) | catalogued as rs200895114, COSV53314853; called by muse, mutect2
- OR5R1 | c.564C>A p.S188= | Silent (SNP) | VAF 105/431 reads (24%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2112C>T p.I704= | Silent (SNP) | VAF 77/306 reads (25%) | called by muse, mutect2, varscan2
- RGS22 | c.2163G>A p.A721= | Silent (SNP) | VAF 118/2036 reads (6%) | catalogued as rs748468054; called by muse, mutect2
- SLC5A1 | c.561C>A p.I187= | Silent (SNP) | VAF 46/666 reads (7%) | called by muse, mutect2
- TMEM221 | c.387G>A p.G129= | Silent (SNP) | VAF 58/714 reads (8%) | called by muse, mutect2
- VN1R4 | c.147G>A p.L49= | Silent (SNP) | VAF 66/342 reads (19%) | called by muse, mutect2, varscan2
- ADGRV1 | c.14517+23C>T | Intron (SNP) | VAF 48/209 reads (23%) | called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532303 C>A | 5'Flank (SNP) | VAF 31/245 reads (13%) | called by muse, mutect2, varscan2
- COL4A5 | c.4803+58T>G | Intron (SNP) | VAF 55/664 reads (8%) | called by muse, mutect2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 17/540 reads (3%) | called by muse, mutect2
- FEM1A | c.*35T>G | 3'UTR (SNP) | VAF 72/877 reads (8%) | called by muse, mutect2
- LRP8 | c.2434+57G>A | Intron (SNP) | VAF 18/146 reads (12%) | called by mutect2, varscan2
- MXRA8 | c.377-26C>T | Intron (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- NEIL1 | c.*44G>T | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2, varscan2
- NSMAF | c.59+333C>T | Intron (SNP) | VAF 26/782 reads (3%) | called by muse, mutect2
- OR10G2 | c.-53C>A | 5'UTR (SNP) | VAF 43/232 reads (19%) | called by muse, mutect2, varscan2
- OR5M11 | c.*24G>A | 3'UTR (SNP) | VAF 57/256 reads (22%) | called by muse, mutect2, varscan2
- RAB40B | c.565+95G>A | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- SGSM2 | c.1965+77G>T | Intron (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- STARD3 | c.1139+41C>T | Intron (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- TAF1L | c.-70C>T | 5'UTR (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- TSC1 | c.1030-52G>T | Intron (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- VPS35L | c.408+18C>T | Intron (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- ZNF474 | c.*61A>G | 3'UTR (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
